Gene-level copy-number profile of tumor specimen TCGA-56-7823-01B from TCGA case TCGA-56-7823, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.4 years (21,344 days).
Specimen TCGA-56-7823-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.1d1c7bd5-220e-49fd-8a01-805960acf777.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-7823-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1517f94e-8ea7-4494-b062-23793e9a8b90

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 17; copy number 2: 17,998; copy number 3: 831; copy number 4: 36,398; copy number 5: 2,523; copy number 6: 731; copy number 7: 237; copy number 8: 58; copy number 9: 411; copy number 10: 422; copy number 11: 26; copy number 12: 24; copy number 16: 19; copy number 26: 5; copy number 29: 32; copy number 41: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-7823-01B-11D-2243-01): tumor purity 0.92, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,619,805–113,199,258, 23 genes: CAPZA1, MRPL53P1, RNU7-70P, MOV10, AL603832.1, RHOC, AL603832.3, PPM1J, AL603832.2, TAFA3, NUTF2P4, LINC01356, LINC01357, AL390729.1, SLC16A1, AKR7A2P1, SLC16A1-AS1, AL390242.1, LRIG2-DT, LRIG2, RLIMP2, AL357055.1, AL357055.2.
- chr4:157,768,013–157,768,113, 1 gene: Y_RNA.
- chr21:46,598,604–46,665,124, 3 genes (within-gene range 0–3): S100B, PRMT2, DSTNP1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 987 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:157,259,742–198,222,513, 715 genes, copy number 9–11 (within-gene range 7–11) (broad region; genes not listed).
- chr10:53,458,197–55,627,942, 8 genes, copy number 12 (within-gene range 2–12): RNA5SP318, AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1.
- chr13:110,305,812–110,561,722, 5 genes, copy number 26 (within-gene range 8–26): COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20.
- chr13:110,863,987–114,223,084, 80 genes, copy number 29–41 (within-gene range 7–41) (broad region; genes not listed).
- chr21:13,349,265–18,486,599, 106 genes, copy number 9–16 (broad region; genes not listed).
- chr21:23,065,491–28,228,667, 73 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
